Surgical pathology report (de-identified scan), TCGA case TCGA-JW-A5VG, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-JW-A5VG-01A (Primary Tumor).

[page 1 of 3]
Results History

Results History

SURGICAL PATHOLOGY (Order

Result History

Result Date and Time

Status

Priority

Final result

Routine

Report Assistance Message

Report and print group assistance enabled. To replace this print group with print groups which are easier to configure, cut-and-paste the following commands into new print group records:

ICD-0-3
Carcinoma, Squamous cell NOS
8670/3
Site Cervix NOS
853.9
J04/4/13

Component Results

Surgical Pathology:

(note)

Name

Date of Birth

Hospital Number

Location

SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

PATHOLOGIC DIAGNOSIS

CERVIX, BIOPSY:

- INVASIVE SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED

Staff Pathologist

Pertinent Clinical Information

SCCA of cervix.

[page 2 of 3]
Clinical Impression: Cancer.

Gross Description

Specimen Material: Cervical biopsy.

The case is received in one part labeled with the patient's name, medical record number and given accession number and it is accompanied by a requisition form labeled with the same name and same accession number.

The specimen is received in formalin labeled "CERVICAL BIOPSY" and consists of a 0.7 x 0.5 x 0.3 cm and 0.9 x 0.3 x 0.2 cm tan-white soft irregular tissue, which is submitted in toto in one cassette.

Pathology Resident

Microscopic Description

Sections of the biopsy show scant amounts of fibrous stroma infiltrated by sheets and nests of poorly differentiated malignant cells with pleomorphic, hyperchromatic nuclei and a moderate amount of cytoplasm. The tumor cells are highlighted by a CK5/6 immunohistochemical stain with appropriate control. These findings are consistent with a poorly differentiated invasive squamous carcinoma.

Intradepartmental consultation: has examined this case and agrees with the findings and interpretation.

These findings were discussed with

The staff pathologist listed below has reviewed this case.

This immunohistochemistry test(s) was developed and its performance characteristics determined by the

and/or affiliated institution. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

****Electronically Signed Out****

Staff Pathologist

Result History

Result Date and Time

Status

In process

Priority

Routine

Report and print group assistance enabled. To replace this print group with print groups which are easier to configure, cut-and-paste the following commands into new print group records:

[page 3 of 3]
Results Routing Details for Order:

Results contact on - Final result

Outcome: Routed using the authorizing provider

Routing Scheme Used:

Routing Scheme Line: 2

Resulting User:

Routing Instant:

Comments: Routing scheme returned no recipients

Current Status: Routing Complete

Status History: Result contact created

Routing started

Routing Complete

Sent:

Message ID:

Recipients:

Resident (MD)

Responsible: Yes

Provider ID: (provider defined by Results Routing)

Result routed to linked user using

Results contact on - In process

Outcome: Result not sent

Resulting User:

Lab In Interface

Routing Instant:

Comments: An message was not sent because no results were filed

Current Status: Routing Complete

Status History: Result contact created

Routing Complete

Order Transmittal Details for Order:

There is no tracking information for this order. Either the order has not gone through order transmittal or the tracking data has been purged from the system due to age.

Performance Data For

Source: NCI Genomic Data Commons file 831ea9ee-c991-4ead-b27c-fc10c5a4fb2e (TCGA-JW-A5VG.679E2EDC-A950-49A4-AC1A-9472CCB3447D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).